Somatic mutation profile of tumor specimen MMRF_1580_1_BM_CD138pos (aliquot MMRF_1580_1_BM_CD138pos_T1_KBS5U_L03499) from MMRF case MMRF_1580, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.0 years (23,388 days).
Specimen MMRF_1580_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d3f2ae-2688-4f1c-83ae-736a7646f1b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1580_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1580_1_PB_CD3pos_C2_KBS5U_L03503; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67fc8c45-831d-4f4f-a87f-1c299b2e324f

The open-access MAF lists 9 somatic variants for this specimen: 2 protein-altering or splice-affecting, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Intron 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR52A5 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100263259, COSV56614108; called by muse, mutect2, varscan2
- ARHGAP24 | c.607G>A p.D203N (on ENST00000395184 / NM_001025616.3; = p.D110N on NM_031305.3) | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF38 | c.*1609C>T | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by mutect2, varscan2
- CADM3 | c.*1665G>A | 3'UTR (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- DKK2 | c.*153A>T | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- EXOC6B | c.1980+1340C>G | Intron (SNP) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- LRRC58 | c.*1443T>G | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- NFKBIA | c.228-305A>C | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- TTC3 | c.845+2264G>A | Intron (SNP) | VAF 8/80 reads (10%) | catalogued as rs1179700715; called by mutect2, varscan2
